CCDI case PBCDIY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/003f9e8a-8bd6-42ed-8a7e-63aa112acba4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Meningeal melanocytoma: ICD-O-3 morphology code: 8728/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.3 years (5,958 days).

Biospecimens (3 samples)
- Sample 0DP8O2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP8O6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP8O9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
